Somatic mutation profile of tumor specimen CDDP-ABK3-TTP1-A (aliquot CDDP-ABK3-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABK3, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73 years.
Specimen CDDP-ABK3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 593484bc-060e-4033-86be-069dd3df354d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABK3-NB1-B (Blood Derived Normal), aliquot CDDP-ABK3-NB1-B-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ec695e0-d95a-4a5b-8719-6f2744916fce

The open-access MAF lists 422 somatic variants for this specimen: 287 protein-altering or splice-affecting, 83 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 83, Nonsense Mutation 33, Intron 25, RNA 12, Splice Region 9, 3'UTR 7, Frame Shift Del 6, 5'UTR 5, Splice Site 4, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3658G>T p.A1220S (on ENST00000404938 / NM_001163941.2; = p.A775S on NM_178559.6) | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as COSV51711803; called by muse, mutect2, varscan2
- ADGRB3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65394417; called by muse, mutect2, varscan2
- ADRA2C | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.16); catalogued as rs1219150182; called by muse, mutect2, varscan2
- AGL | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 20/429 reads (5%) | catalogued as rs1223038627; called by muse, mutect2
- AHNAK2 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV60921750; called by muse, mutect2, varscan2
- B4GALNT4 | c.2868C>T p.H956= | Splice Region (SNP) | VAF 22/96 reads (23%) | catalogued as rs767133849; called by muse, mutect2, varscan2
- BLM | c.2361G>C p.K787N | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100757236; called by muse, mutect2, varscan2
- C20orf204 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1413339076; called by muse, mutect2, varscan2
- C3orf20 | c.1102G>C p.A368P | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.192); catalogued as COSV53788495; called by muse, mutect2, varscan2
- CCDC178 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.682); catalogued as rs776429737; called by muse, mutect2, varscan2
- CSMD1 | c.2972G>T p.G991V (on ENST00000520002; = p.G990V on NM_033225.6) | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144284; called by muse, mutect2, varscan2
- CSMD2 | c.8221C>A p.Q2741K | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs771710422, COSV53958840; called by muse, mutect2, varscan2
- CYP11B2 | c.1508A>T p.N503I | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs146765393; called by muse, mutect2, varscan2
- DKK2 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 126/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53393858; called by muse, mutect2, varscan2
- DPY19L2 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV60545210, COSV60545274; called by muse, mutect2, varscan2
- EIF2S2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.076); catalogued as COSV100895017; called by muse, mutect2, varscan2
- EPHA3 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.133); catalogued as COSV60693371, COSV60707181; called by muse, mutect2, varscan2
- FBXL7 | c.1443C>A p.C481* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100308711; called by muse, mutect2, varscan2
- FBXW4 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as rs1220593863; called by muse, mutect2
- FCGR3A | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 68/773 reads (9%) | catalogued as COSV63460190; called by muse, mutect2
- FCRL4 | c.1359T>C p.D453= | Splice Region (SNP) | VAF 133/304 reads (44%) | catalogued as rs200321040; called by muse, mutect2, varscan2
- FRRS1L | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200912119; called by muse, mutect2, varscan2
- FTHL17 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 47/86 reads (55%) | catalogued as rs759407328; called by muse, mutect2, varscan2
- GTF3C1 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649738; called by muse, mutect2, varscan2
- HOXD11 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs1031471383; called by mutect2, varscan2
- HYDIN | c.7544G>A p.R2515H | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776395603, COSV59253798; called by muse, mutect2
- INPP4B | c.2486C>A p.T829K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.303); catalogued as COSV53710452, COSV53738323; called by muse, mutect2, varscan2
- IRS2 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV101019423; called by muse, mutect2, varscan2
- KCNH2 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 102/199 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as CD099617; called by muse, mutect2, varscan2
- KDM4E | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71678347; called by muse, mutect2, varscan2
- KNSTRN | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51103388, COSV51103522; called by muse, mutect2, varscan2
- LAMA5 | c.5611G>C p.D1871H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV53370889; called by muse, mutect2, varscan2
- LILRB2 | c.927del p.S310Afs*7 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs1390503826; called by mutect2, pindel
- LILRB5 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV60259238; called by muse, mutect2, varscan2
- LRP1B | c.10402G>T p.E3468* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV67199606, COSV67278847; called by muse, mutect2, varscan2
- LRP1B | c.1638T>A p.D546E | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV67201071; called by muse, mutect2, varscan2
- LRRC37B | c.1691del p.G564Efs*21 | Frame Shift Del (DEL) | VAF 46/154 reads (30%) | catalogued as COSV58953585, COSV58954969; called by mutect2, varscan2
- LRRFIP1 | c.1657G>A p.E553K (on ENST00000392000 / NM_001137552.2; = p.E529K on NM_004735.4) | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1459991417; called by muse, mutect2, varscan2
- MIS18A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as rs1368135876; called by muse, mutect2, varscan2
- MTSS2 | c.1308C>T p.H436= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as rs139138667; called by muse, mutect2, varscan2
- MUC16 | c.37619G>T p.G12540V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV67471722; called by muse, mutect2, varscan2
- MUC4 | c.13367C>T p.A4456V (on ENST00000463781 / NM_018406.7; = p.A220V on NM_004532.6) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV57789350; called by muse, mutect2
- MUC6 | c.4118C>A p.T1373N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs757897020; called by muse, varscan2
- NME8 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52249812; called by muse, mutect2, varscan2
- NOTCH3 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779780504, COSV54635749; called by muse, mutect2, varscan2
- NTRK2 | c.1822G>T p.V608L (on ENST00000323115 / NM_001369534.1; = p.V624L on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1194954580, COSV52858767; called by muse, mutect2, varscan2
- OR13F1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV58252463; called by muse, varscan2
- OR2L13 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63547965, COSV63552086, COSV63559650; called by muse, mutect2, varscan2
- OR2M2 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 177/395 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100677187, COSV100677301; called by muse, mutect2, varscan2
- OR2T10 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs748166599; called by muse, mutect2, varscan2
- OR4A15 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV59035597; called by muse, mutect2, varscan2
- OR4C6 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58602789; called by muse, mutect2, varscan2
- OR6C65 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs892470804; called by muse, mutect2, varscan2
- PBXIP1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as rs751951283, COSV63777068; called by muse, mutect2, varscan2
- PCDH8 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100131426; called by muse, mutect2, varscan2
- PCDHA5 | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100972255; called by muse, mutect2, varscan2
- PCOLCE2 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.326); catalogued as rs530037755; called by muse, mutect2, varscan2
- PDZRN3 | c.2789C>T p.T930M | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs745814121, COSV55195914, COSV55209287; called by muse, mutect2, varscan2
- PLEKHA5 | c.1848G>T p.L616= | Splice Region (SNP) | VAF 22/98 reads (22%) | catalogued as rs765777969; called by muse, mutect2, varscan2
- PPEF2 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as COSV54421373; called by muse, mutect2, varscan2
- RAD51 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV51112294; called by muse, mutect2, varscan2
- RBBP8NL | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV53348044; called by muse, mutect2, varscan2
- RNASEL | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 144/276 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV100842588; called by muse, mutect2, varscan2
- RNF150 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as rs763659268; called by muse, mutect2, varscan2
- RTL1 | c.3301G>A p.V1101M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs137942742, COSV66017044; called by muse, mutect2, varscan2
- SIPA1L3 | c.1562A>T p.E521V | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV55909273; called by muse, mutect2, varscan2
- SIX6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1237413105, COSV59803403; called by muse, mutect2, varscan2
- SLC7A10 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs758946928, COSV53503744; called by muse, mutect2, varscan2
- SLITRK3 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1490316717, COSV53852040; called by muse, mutect2, varscan2
- SPATA31E1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs150375971; called by muse, mutect2, varscan2
- SPEN | c.2354A>G p.Y785C | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs777197196; called by muse, mutect2, varscan2
- SPTAN1 | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs769801752; called by mutect2, varscan2
- SPTAN1 | c.5075C>T p.S1692F | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63989433; called by muse, varscan2
- SPTBN5 | c.6016G>T p.G2006W | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547212592; called by muse, mutect2, varscan2
- TBX5 | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763390789; called by muse, mutect2, varscan2
- TCERG1 | c.1984C>G p.R662G | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757418960, COSV57035797; called by muse, mutect2, varscan2
- TCP1 | c.1019T>C p.F340S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776530809; called by muse, mutect2, varscan2
- TDRD3 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.047); catalogued as rs918079029; called by muse, mutect2, varscan2
- TEX13C | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as COSV51076803, COSV52977312; called by muse, mutect2, varscan2
- TGFBR3 | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53026135; called by muse, mutect2, varscan2
- THRAP3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | catalogued as COSV63566841; called by muse, mutect2
- TMC5 | c.1432G>A p.V478M (on ENST00000396229 / NM_001105248.1; = p.V232M on NM_024780.5) | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs764397430, COSV54908528; called by muse, mutect2, varscan2
- TMEM131 | c.4850G>T p.R1617L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV51787920, COSV99488244; called by muse, mutect2
- TMEM39B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as rs778742208, COSV60380301, COSV60380736; called by muse, mutect2, varscan2
- TTC17 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1206680715, COSV50018417; called by muse, mutect2
- TTLL10 | c.1052C>A p.T351K (on ENST00000379289 / NM_001130045.2; = p.T278K on NM_153254.3) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV64960025; called by muse, mutect2, varscan2
- WNK2 | c.5306G>T p.R1769L (on ENST00000297954 / NM_001282394.1; = p.R1732L on NM_006648.3) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.393); catalogued as rs563807204; called by muse, mutect2, varscan2
- ZNF10 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs765801272; called by muse, mutect2, varscan2
- ZNF606 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168658203; called by muse, mutect2, varscan2
- ABCA13 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ABR | c.286C>G p.L96V (on ENST00000302538 / NM_021962.5; = p.L59V on NM_001092.5) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ACTG2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, varscan2
- ADRA2C | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.1291T>C p.W431R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- AGRN | c.464-5T>A | Splice Region (SNP) | VAF 82/284 reads (29%) | called by muse, mutect2, varscan2
- AHNAK2 | c.1428G>C p.Q476H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ALOX15 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 60/275 reads (22%) | called by muse, mutect2, varscan2
- ANKDD1B | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 52/181 reads (29%) | called by muse, mutect2, varscan2
- ANKRD50 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.461C>T p.P154L (on ENST00000398564; = p.P130L on NM_014629.4) | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF33 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASB18 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ATF6 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP1A2 | c.2923C>A p.L975I | Missense Mutation (SNP) | VAF 114/209 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- ATRN | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- AVPR1A | c.1093T>A p.C365S | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BMP7 | c.1190C>G p.A397G | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BRAF | c.1915_1916insTAA p.A638_T639insI (on ENST00000288602 / NM_001374244.1; = p.A598_T599insI on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 134/381 reads (35%) | called by mutect2, pindel, varscan2
- BRCA1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, varscan2
- BRCA2 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2
- BTBD11 | c.2263G>T p.E755* (on ENST00000280758 / NM_001018072.2; = p.E292* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- C14orf39 | c.1477T>C p.F493L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- C20orf85 | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C4orf50 | c.462G>T p.Q154H (on ENST00000324058; = p.Q1386H on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, varscan2
- CALHM1 | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC138 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CD109 | c.3941C>A p.A1314D | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CD22 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CDH10 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.3040G>C p.V1014L | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- CELSR3 | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 72/259 reads (28%) | called by muse, mutect2, varscan2
- CFAP52 | c.1335G>C p.Q445H | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CFTR | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CHD1 | c.4316C>A p.S1439* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- CHERP | c.2682T>A p.Y894* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | called by muse, mutect2, varscan2
- CLEC4G | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMTR2 | c.1531dup p.C511Lfs*4 | Frame Shift Ins (INS) | VAF 60/130 reads (46%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- COL15A1 | c.3387del p.G1130Dfs*23 | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | called by mutect2, pindel, varscan2
- COL4A1 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.5650A>T p.T1884S (on ENST00000312481; = p.T1880S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CRIPT | c.27A>T p.K9N | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CWH43 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DCDC1 | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DCHS1 | c.4318C>A p.P1440T | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DNAH14 | c.4666G>T p.E1556* (on ENST00000445597; = p.E1961* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- DNAH2 | c.3911C>G p.S1304* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- DPY19L2 | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DST | c.12155C>A p.A4052D (on ENST00000361203 / NM_001374722.1; = p.A1640D on NM_015548.5) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DYRK4 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EEFSEC | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- EPX | c.1853C>A p.A618D | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ERBB4 | c.3013C>T p.Q1005* | Nonsense Mutation (SNP) | VAF 20/344 reads (6%) | called by muse, mutect2
- ERCC6L2 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.131); called by muse, varscan2
- F5 | c.1748C>A p.S583* | Nonsense Mutation (SNP) | VAF 117/303 reads (39%) | called by muse, mutect2, varscan2
- FAM47A | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FAM71F1 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2
- FARSA | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAT2 | c.6755C>T p.S2252L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- FCRL5 | c.2727A>T p.Q909H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FLG | c.10092T>A p.H3364Q | Missense Mutation (SNP) | VAF 469/844 reads (56%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FLG | c.1625C>G p.S542* | Nonsense Mutation (SNP) | VAF 131/713 reads (18%) | called by muse, mutect2, varscan2
- FRMPD4 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRG3 | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- GJB5 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GNA11 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- GOLGA6C | c.1820A>T p.Q607L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by mutect2, varscan2
- GPIHBP1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRB10 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2
- GREB1 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 87/307 reads (28%) | called by muse, mutect2, varscan2
- GRIA4 | c.89-1G>A p.X30_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2
- GRK4 | c.469del p.E157Nfs*26 (on ENST00000398052 / NM_182982.3; = p.E125Nfs*26 on NM_005307.3) | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- HBP1 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD4 | c.8777C>G p.A2926G | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1039T>C p.Y347H (on ENST00000354667 / NM_031243.3; = p.Y335H on NM_002137.4) | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ICA1L | c.340T>C p.C114R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGHV3-16 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- INA | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- INTS1 | c.4638G>T p.Q1546H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- INTS4 | c.1886C>G p.P629R | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQCG | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRS4 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ITPRIPL1 | c.1111C>T p.Q371* (on ENST00000439118 / NM_001008949.3; = p.Q379* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- KANK3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- KAT7 | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNV1 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF9 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- KLHL30 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2A | c.7120G>T p.G2374W | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KRTAP26-1 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- KRTAP5-4 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 117/453 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- LHX4 | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- LIMCH1 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, varscan2
- LRP1 | c.7911del p.M2637Ifs*16 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- LVRN | c.2038-6C>A | Splice Region (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2
- MAP2K1 | c.961-5T>A | Splice Region (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
- MAPRE1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- MAX | c.64-2A>T p.X22_splice | Splice Site (SNP) | VAF 125/344 reads (36%) | called by muse, mutect2, varscan2
- MDGA2 | c.2206C>G p.R736G (on ENST00000399232 / NM_001113498.2; = p.R438G on NM_182830.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MGAM | c.4618G>C p.G1540R | Missense Mutation (SNP) | VAF 74/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM2 | c.3569G>A p.G1190D | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIS18A | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MLXIP | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- MRPL21 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MUC16 | c.33752C>A p.P11251Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MXD3 | c.581A>C p.Q194P | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MYF5 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH10 | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYH2 | c.4573G>T p.G1525* | Nonsense Mutation (SNP) | VAF 109/317 reads (34%) | called by muse, mutect2, varscan2
- NABP1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NDOR1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NELL1 | c.1059T>G p.C353W | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NRCAM | c.3305T>A p.V1102E | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OPN5 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR1J2 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2G3 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR6C65 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PABPC4L | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- PAF1 | c.77+3G>T | Splice Region (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- PARD3B | c.3226G>A p.E1076K (on ENST00000406610 / NM_001302769.2; = p.E1007K on NM_057177.7) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PCDHGB1 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGC4 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PDE3B | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- PHF14 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGR | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKD1L1 | c.4527C>A p.C1509* | Nonsense Mutation (SNP) | VAF 88/335 reads (26%) | called by muse, mutect2, varscan2
- PKN1 | c.2393G>T p.W798L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCD4 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCD4 | c.1850C>A p.P617H | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLEKHM2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLSCR4 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- POM121L2 | c.2651G>A p.R884K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POTEB3 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- POU3F2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRCP | c.974A>C p.Q325P | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PRKN | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 101/239 reads (42%) | called by muse, mutect2, varscan2
- PTH1R | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRD | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RAI1 | c.3276dup p.K1093Qfs*73 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- RBM24 | c.193G>T p.A65S (on ENST00000379052 / NM_001143942.2; = p.A20S on NM_153020.2) | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RERG | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RERG | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RRBP1 | c.3579G>T p.Q1193H (on ENST00000377813 / NM_001365613.2; = p.Q760H on NM_004587.3) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RSPH4A | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL3 | c.1562C>G p.S521* (on ENST00000367770; = p.S467* on NM_020423.7) | Nonsense Mutation (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- SDK1 | c.5766G>T p.W1922C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA7A | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SGK1 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SH3D21 | c.2179G>C p.E727Q (on ENST00000453908 / NM_001162530.2; = p.E616Q on NM_024676.5) | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIGLEC10 | c.125_126del p.S42Ffs*24 | Frame Shift Del (DEL) | VAF 42/165 reads (25%) | called by pindel, varscan2
- SKA3 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SLC35G4 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 55/354 reads (16%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC9A8 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO2A1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLITRK3 | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLMAP | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- SNTG1 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SOCS6 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPAG9 | c.783+3G>C | Splice Region (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2, varscan2
- SPATA13 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A1 | c.1610T>A p.L537Q | Missense Mutation (SNP) | VAF 106/448 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SPATA31A3 | c.2036C>A p.P679Q | Missense Mutation (SNP) | VAF 92/379 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- SPPL2B | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SRSF6 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ST3GAL2 | c.531G>T p.M177I | Missense Mutation (SNP) | VAF 20/31 reads (65%) | PolyPhen benign (0.012); called by muse, varscan2
- STPG1 | c.409C>G p.P137A (on ENST00000337248 / NM_001199013.2; = p.P90A on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- STXBP5 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SULT4A1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- SUZ12 | c.817A>T p.N273Y | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- TGFB1 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THSD1 | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TIAM1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- TOX | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV29-1 | c.252C>A p.S84R | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRIM47 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- TRIM51GP | c.557T>A p.M186K | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TSPEAR | c.713C>A p.A238E | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TTC33 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTLL2 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TTN | c.5573C>T p.A1858V (on ENST00000591111; = p.A1812V on NM_003319.4) | Missense Mutation (SNP) | VAF 97/362 reads (27%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- U2SURP | c.2684G>C p.R895P | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- UNC80 | c.8149C>T p.P2717S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP48 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VCL | c.1777C>G p.Q593E | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- VPS16 | c.1367G>T p.R456M | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR11 | c.3104G>A p.C1035Y | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WDR75 | c.2126A>T p.K709I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZBTB46 | c.1426T>C p.C476R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM2 | c.1412A>T p.K471M | Missense Mutation (SNP) | VAF 128/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF155 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF208 | c.336C>A p.H112Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF485 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZNF517 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF521 | c.1307C>A p.A436D | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF736 | c.4-1G>T p.X2_splice | Splice Site (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- ZNF831 | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSWIM5 | c.3244A>G p.T1082A | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1753C>T p.L585= | Silent (SNP) | VAF 82/326 reads (25%) | called by muse, mutect2, varscan2
- ALAD | c.576G>A p.S192= | Silent (SNP) | VAF 39/393 reads (10%) | catalogued as rs753037931, COSV99474986; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP42 | c.1116G>A p.K372= | Silent (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.2001G>C p.S667= | Silent (SNP) | VAF 64/277 reads (23%) | catalogued as COSV101182266; called by muse, mutect2, varscan2
- BEST4 | c.1155C>T p.S385= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs925236917; called by muse, mutect2, varscan2
- BIRC6 | c.12970C>T p.L4324= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV70199978, COSV70208172; called by muse, varscan2
- C1orf94 | c.1149C>A p.P383= (on ENST00000488417 / NM_001134734.2; = p.P193= on NM_032884.5) | Silent (SNP) | VAF 132/431 reads (31%) | catalogued as COSV100974975; called by muse, mutect2, varscan2
- CACNG8 | c.177C>A p.A59= | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- CAGE1 | c.2073G>T p.L691= (on ENST00000512086; = p.L555= on NM_205864.3) | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- CARD8 | c.1404G>C p.L468= (on ENST00000651546 / NM_001184900.3; = p.L418= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV62875143; called by muse, mutect2, varscan2
- CASQ1 | c.657A>C p.A219= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- CCDC168 | c.10308G>T p.R3436= | Silent (SNP) | VAF 57/220 reads (26%) | called by muse, mutect2, varscan2
- CCDC171 | c.2307T>C p.I769= | Silent (SNP) | VAF 61/226 reads (27%) | called by muse, mutect2, varscan2
- CDH20 | c.2043G>C p.A681= | Silent (SNP) | VAF 71/228 reads (31%) | catalogued as rs149566490; called by muse, mutect2, varscan2
- CDH24 | c.1965G>C p.L655= | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- CENPE | c.6861T>C p.N2287= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- CEP89 | c.855C>T p.L285= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs1021751550, COSV59861698; called by muse, mutect2, varscan2
- CFC1 | c.232C>A p.R78= | Silent (SNP) | VAF 74/636 reads (12%) | catalogued as rs1318519716, CM002873; called by muse, mutect2, varscan2
- CLDN11 | c.33C>T p.F11= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV99290860; called by muse, mutect2
- CLEC6A | c.99T>C p.A33= | Silent (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- CLPTM1L | c.1005C>T p.V335= | Silent (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- COPZ2 | c.168G>T p.G56= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- DISP3 | c.843G>A p.A281= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV53820741; called by muse, mutect2, varscan2
- DLG5 | c.3585C>T p.P1195= | Silent (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- DNTT | c.987C>A p.T329= | Silent (SNP) | VAF 21/90 reads (23%) | called by muse, varscan2
- DOCK4 | c.3633C>G p.L1211= | Silent (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- DSG4 | c.1386G>T p.G462= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV57389517; called by muse, mutect2, varscan2
- EIF3D | c.537G>A p.L179= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- EPHA3 | c.1602C>A p.S534= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- ETV6 | c.249C>T p.D83= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV67149835; called by muse, mutect2, varscan2
- EVPL | c.1587A>T p.T529= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as COSV100044577; called by muse, mutect2, varscan2
- FAM120A | c.2517C>T p.R839= | Silent (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- FBH1 | c.3126C>G p.V1042= (on ENST00000362091 / NM_178150.3; = p.V1093= on NM_032807.4) | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- FEZF1 | c.1296G>T p.T432= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- FLG | c.519T>C p.Y173= | Silent (SNP) | VAF 284/493 reads (58%) | called by muse, mutect2, varscan2
- GABRG1 | c.1053T>C p.Y351= | Silent (SNP) | VAF 41/220 reads (19%) | called by muse, mutect2, varscan2
- GPR135 | c.1056G>C p.L352= | Silent (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- GRIA2 | c.1341T>A p.V447= | Silent (SNP) | VAF 130/336 reads (39%) | called by muse, mutect2, varscan2
- HELT | c.186G>A p.L62= | Silent (SNP) | VAF 125/298 reads (42%) | called by muse, mutect2, varscan2
- IGHD | c.762C>T p.P254= | Silent (SNP) | VAF 119/378 reads (31%) | called by muse, mutect2, varscan2
- KCNH3 | c.906C>T p.Y302= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs752429985; called by muse, mutect2, varscan2
- KIF21B | c.4377G>A p.L1459= (on ENST00000422435 / NM_001252100.2; = p.L1446= on NM_017596.4) | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- KRT33A | c.639G>T p.V213= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- KRT83 | c.642G>T p.V214= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- LILRA2 | c.945G>T p.L315= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99253750; called by muse, mutect2, varscan2
- LMO1 | c.30G>C p.V10= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2
- LONRF3 | c.807A>T p.A269= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, varscan2
- MAPK8IP3 | c.3393C>T p.V1131= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- MED26 | c.276G>A p.A92= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs774277841; called by muse, mutect2, varscan2
- MYH6 | c.966C>A p.A322= | Silent (SNP) | VAF 103/300 reads (34%) | called by muse, mutect2, varscan2
- OR13D1 | c.294C>A p.L98= | Silent (SNP) | VAF 84/280 reads (30%) | called by muse, mutect2, varscan2
- PDK1 | c.1179A>T p.S393= | Silent (SNP) | VAF 63/189 reads (33%) | called by muse, mutect2, varscan2
- PER2 | c.1164A>T p.S388= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- PYGL | c.673C>T p.L225= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- PZP | c.1752A>G p.A584= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- RB1CC1 | c.1032A>T p.I344= | Silent (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- RBM33 | c.834G>T p.R278= | Silent (SNP) | VAF 46/228 reads (20%) | called by muse, varscan2
- RNF150 | c.765C>A p.A255= | Silent (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- RO60 | c.1173C>T p.N391= | Silent (SNP) | VAF 47/237 reads (20%) | catalogued as rs780813644; called by muse, mutect2, varscan2
- RRAGB | c.645A>T p.P215= (on ENST00000262850 / NM_016656.4; = p.P187= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- RYR2 | c.1749A>T p.P583= | Silent (SNP) | VAF 71/167 reads (43%) | called by muse, mutect2, varscan2
- RYR2 | c.9462A>G p.A3154= | Silent (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- SBF2 | c.1038C>T p.S346= | Silent (SNP) | VAF 54/172 reads (31%) | called by muse, varscan2
- SECISBP2L | c.2082C>G p.L694= (on ENST00000559471 / NM_001193489.2; = p.L649= on NM_014701.4) | Silent (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- SEZ6L | c.2562G>T p.G854= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1305696923; called by muse, mutect2, varscan2
- SLC9A4 | c.1420C>T p.L474= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- SOCS6 | c.273G>T p.A91= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs781334187; called by mutect2, varscan2
- SPATA31A1 | c.1716C>A p.S572= | Silent (SNP) | VAF 22/57 reads (39%) | called by mutect2, varscan2
- SPDYE6 | c.852C>G p.L284= | Silent (SNP) | VAF 154/2679 reads (6%) | called by muse, mutect2
- SPG21 | c.519G>T p.V173= | Silent (SNP) | VAF 98/377 reads (26%) | called by muse, mutect2, varscan2
- STK39 | c.1239A>G p.P413= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- SULT4A1 | c.540G>A p.Q180= | Silent (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- TAGAP | c.120G>A p.E40= | Silent (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- TGM5 | c.294C>A p.T98= | Silent (SNP) | VAF 104/331 reads (31%) | called by muse, mutect2, varscan2
- THNSL2 | c.870C>T p.I290= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- TMEM236 | c.981G>T p.V327= | Silent (SNP) | VAF 160/509 reads (31%) | called by muse, mutect2, varscan2
- TUFM | c.165G>A p.V55= | Silent (SNP) | VAF 17/307 reads (6%) | called by muse, mutect2
- VPS13A | c.5925A>G p.R1975= | Silent (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- WNK1 | c.5316T>A p.T1772= (on ENST00000315939 / NM_018979.4; = p.T1525= on NM_014823.3) | Silent (SNP) | VAF 116/384 reads (30%) | called by muse, mutect2, varscan2
- XKR3 | c.105T>C p.F35= | Silent (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- XKR4 | c.1614C>G p.P538= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- ZBTB7B | c.951C>T p.Y317= (on ENST00000292176; = p.Y351= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/192 reads (60%) | catalogued as rs1347581304; called by muse, mutect2, varscan2
- ZNF835 | c.561G>T p.T187= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs752611539, COSV101606232; called by muse, mutect2, varscan2
- AL450442.1 | n.815C>T | RNA (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- ANK2 | c.11611-518G>C | Intron (SNP) | VAF 54/151 reads (36%) | catalogued as rs1291215553; called by muse, mutect2, varscan2
- AP002495.1 | c.436+316G>A | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as rs1426699218; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.-20G>A | 5'UTR (SNP) | VAF 66/127 reads (52%) | catalogued as rs772698025; called by muse, mutect2, varscan2
- BMT2 | c.160+4363A>T | Intron (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- CACNB2 | c.213+110315G>T | Intron (SNP) | VAF 89/322 reads (28%) | catalogued as rs967567029; called by muse, mutect2, varscan2
- CALY | c.246+118G>T | Intron (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- CEROX1 | n.3110G>T | RNA (SNP) | VAF 103/316 reads (33%) | called by muse, mutect2, varscan2
- CINP | chr14:102362897 C>T | 5'Flank (SNP) | VAF 18/52 reads (35%) | catalogued as rs1281352472; called by muse, mutect2, varscan2
- CRTAM | c.-18A>T | 5'UTR (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- ERI3 | c.490-3081A>G | Intron (SNP) | VAF 32/91 reads (35%) | catalogued as rs1297206937; called by muse, mutect2, varscan2
- ESRRG | c.*334T>C | 3'UTR (SNP) | VAF 57/245 reads (23%) | called by muse, mutect2, varscan2
- FRMPD2B | n.803G>T | RNA (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- GIMAP6 | c.*109G>A | 3'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- GLUL | c.*4G>C | 3'UTR (SNP) | VAF 48/397 reads (12%) | called by muse, mutect2, varscan2
- GTF2A1L | c.-18G>T | 5'UTR (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- H3-3B | chr17:75784641 C>A | 5'Flank (SNP) | VAF 59/262 reads (23%) | called by muse, mutect2, varscan2
- HERC2P4 | n.330G>T | RNA (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- IQCC | c.42+77G>A | Intron (SNP) | VAF 69/222 reads (31%) | called by muse, mutect2, varscan2
- ITGA4 | c.*2577G>T | 3'UTR (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- KLHL14 | c.-44+564G>A | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as rs1391065675; called by mutect2, varscan2
- LINC00303 | n.167G>T | RNA (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- MASP2 | c.412+24C>T | Intron (SNP) | VAF 42/136 reads (31%) | catalogued as rs200191909; called by muse, mutect2, varscan2
- MCCC2 | c.130-22G>C | Intron (SNP) | VAF 51/201 reads (25%) | called by muse, varscan2
- MIR646 | n.1G>A | RNA (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- MUC19 | n.5442C>T | RNA (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- MYO15A | c.5212-43C>T | Intron (SNP) | VAF 32/104 reads (31%) | catalogued as rs1186737979; called by muse, mutect2, varscan2
- MYO19 | c.894+713T>C | Intron (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12866C>A | Intron (SNP) | VAF 79/215 reads (37%) | catalogued as rs1465101987; called by muse, mutect2, varscan2
- NDUFS7 | c.228+623C>G | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- NFYC | c.*642G>A | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- NXF5 | n.363G>T | RNA (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- NXPH4 | c.58-3550C>T | Intron (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- NXPH4 | c.58-3549C>T | Intron (SNP) | VAF 25/90 reads (28%) | catalogued as rs1278708507; called by muse, mutect2, varscan2
- OAS1 | c.1039-734G>T | Intron (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- PTPRT | c.2983-774G>T | Intron (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- SLC2A6 | c.463-42A>T | Intron (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- SLC7A5P2 | n.330C>G | RNA (SNP) | VAF 85/544 reads (16%) | called by muse, mutect2, varscan2
- SPANXB1 | c.-56C>A | 5'UTR (SNP) | VAF 80/306 reads (26%) | catalogued as COSV71886019; called by muse, varscan2
- SPG11 | c.3454-25C>T | Intron (SNP) | VAF 64/218 reads (29%) | called by muse, mutect2, varscan2
- STRBP | c.-8A>T | 5'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- SUSD4 | c.148+4184del | Intron (DEL) | VAF 48/259 reads (19%) | called by mutect2, pindel, varscan2
- SYNRG | c.78-123A>T | Intron (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- SYT14 | c.*76C>T | 3'UTR (SNP) | VAF 105/586 reads (18%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+55022G>T | Intron (SNP) | VAF 55/210 reads (26%) | catalogued as rs1462334338; called by muse, mutect2, varscan2
- THSD4 | c.-80+15269T>A | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- TRBV25OR9-2 | n.176G>T | RNA (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.10360+4027G>C | Intron (SNP) | VAF 41/164 reads (25%) | catalogued as COSV59971631; called by muse, mutect2, varscan2
- UNC5D | c.*2391G>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- WASH8P | n.923G>A | RNA (SNP) | VAF 153/624 reads (25%) | catalogued as rs782150996; called by muse, mutect2, varscan2
- ZNF22 | chr10:45000381 G>A | 5'Flank (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- ZNF503-AS2 | n.382C>G | RNA (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
